MMRF case MMRF_1777 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c6dab2e9-c103-4beb-bbf3-30dc49982a63

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.7 years (24,742 days); ISS stage: I; Days to last known disease status: 981 days (2.7 years); Days to last follow up: 981 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 97 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 405 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 30 days; Days to treatment end: 92 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 405 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 163 days; Days to treatment end: 405 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 441 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 88.3 mg/dL; Immunoglobulin G 6.2 g/L; Immunoglobulin A 2.23 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 71 µmol/L; Calcium 2.48 mmol/L; Albumin 38 g/L; Glucose 6.1 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 71 (ECOG 1): Hemoglobin 7.5 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 3.21 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 102 µmol/L; Calcium 2.44 mmol/L; Glucose 6 mmol/L.
- Day 162 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 9.1 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 102 µmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.7 mmol/L.
- Day 288 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 6.6 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 94 µmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.3 mmol/L.
- Day 369 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Hemoglobin 7.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 98 µmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL.
- Day 490 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Hemoglobin 7.32 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 109 µmol/L; Calcium 2.34 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL.
- Day 546: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 104 µmol/L; Calcium 2.26 mmol/L; Albumin 45 g/L.
- Day 610: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.59 mg/dL; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.4 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 165 µmol/L; Calcium 2.34 mmol/L; Albumin 45 g/L.
- Day 750 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.276 mg/dL; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 138 µmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL.
- Day 918: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.269 mg/dL; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 8.12 mmol/L; Absolute Neutrophil 4.1 ×10⁹/L; Creatinine 161 µmol/L; Calcium 2.42 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL.
- Day 981: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.228 mg/dL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 204 µmol/L; Calcium 2.37 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL.

Other clinical attributes
- Day -6: Weight: 70 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1777_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1777_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
